Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A45V, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A45V-01A (Primary Tumor).

DOB:
Physic

Sex: F

Received:

Pathologist:

Case type: Surgical History

Accession:

** Case imported from legacy computer system. The format of this report does not match the original case. **
** For cases prior to section "SPECIMEN" may have been added. **

SUPPLEMENTAL REPORT

COMMENT:

Decalcification of mandibular bone revealed involvement of cortical bone by squamous carcinoma.

Entire report and diagnosis completed by:
Report released by:

SIGNATURE:

ENTIRE REPORT ELECTRONICALLY SIGNED BY:

DIAGNOSIS

(A) RIGHT HEMIMANDIBULECTOMY:
INVASIVE WELL DIFFERENTIATED SQUAMOUS CARCINOMA, MARGINS FREE OF TUMOR.

ICD-0-3

Carcinoma, Squamous cell, NOS 8070/3
Sites oral cavity C06.9

mw
10/1/12

Entire report and diagnosis completed by:
Report released by:

GROSS DESCRIPTION

(A) RIGHT HEMIMANDIBULECTOMY - Overall measurement of 15.0 x 2.5 x 1.5 cm. Attached to the anterior bony segment is a soft tissue fragment with overall measurements of 4.5 x 3.0 x 2.0 cm. Within the soft tissue an ulcerated and necrotic lesion 2.5 x 1.0 x 1.0 cm is noted. The anterior surgical margin appears uninvolved and the deep soft tissue margin is free of gross tumor. Representative sections are submitted from anterior to posterior as A1-A8.

SNOMED CODES

M-01100 M-09400 M-54000 T-1A000

mw
9/9/12

Source: NCI Genomic Data Commons file fdac347d-1c08-45c5-bb05-fcc6c037774b (TCGA-CV-A45V.0557AC56-8DFB-40A2-9DE4-84F9794D25A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).